Somatic mutation profile of tumor specimen TCGA-AG-A00C-01A (aliquot TCGA-AG-A00C-01A-01W-A00K-09) from TCGA case TCGA-AG-A00C, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 49.8 years (18,201 days).
Specimen TCGA-AG-A00C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b73c64c-e4ad-4ff4-9377-f07a384d4915.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-A00C-10A (Blood Derived Normal), aliquot TCGA-AG-A00C-10A-01W-A00K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/024088aa-6222-4b25-9284-8e589a682c8c

The open-access MAF lists 143 somatic variants for this specimen: 113 protein-altering or splice-affecting, 29 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 29, Nonsense Mutation 11, Frame Shift Del 4, Splice Site 3, Frame Shift Ins 3, Splice Region 1, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4189G>T p.E1397* | Nonsense Mutation (SNP) | VAF 89/230 reads (39%) | hotspot (GDC flag); catalogued as CM992136, COSV57321785, COSV57346425; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 13/51 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 57/118 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.2882T>G p.L961R | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV70028671; called by muse, mutect2, varscan2
- ACAN | c.7561C>T p.R2521C (on ENST00000560601 / NM_001369268.1; = p.R2483C on NM_013227.3) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781181702, COSV61359578; called by muse, mutect2
- ADAMTS16 | c.1606G>A p.D536N | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs752096825; called by muse, mutect2, varscan2
- ADGRL2 | c.659T>C p.F220S | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as rs1387132521, COSV54666522; called by muse, mutect2, varscan2
- ANO4 | c.881C>T p.A294V (on ENST00000392977 / NM_001286615.2; = p.A259V on NM_178826.4) | Missense Mutation (SNP) | VAF 14/420 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1258502826, COSV54590058; called by muse, mutect2
- APC | c.3625G>T p.E1209* | Nonsense Mutation (SNP) | VAF 95/247 reads (38%) | catalogued as CD011096, COSV57327136; called by muse, mutect2, varscan2
- ARHGAP25 | c.1835G>A p.R612H (on ENST00000409202 / NM_001007231.3; = p.R604H on NM_014882.3) | Missense Mutation (SNP) | VAF 139/404 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs374053151; called by muse, mutect2, varscan2
- ASMTL | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs759594201; called by muse, varscan2
- ASXL2 | c.869del p.H290Pfs*21 | Frame Shift Del (DEL) | VAF 55/193 reads (28%) | catalogued as COSV55458713; called by mutect2, pindel, varscan2
- CATSPER4 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs551550512; called by muse, mutect2, varscan2
- CDHR2 | c.2908C>T p.R970* | Nonsense Mutation (SNP) | VAF 43/143 reads (30%) | catalogued as rs946480691; called by muse, mutect2, varscan2
- CEP152 | c.5006C>T p.S1669L (on ENST00000380950 / NM_001194998.2; = p.S1613L on NM_014985.4) | Missense Mutation (SNP) | VAF 184/524 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.315); catalogued as COSV57859412; called by muse, mutect2, varscan2
- CHODL | c.289G>T p.G97C | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54735447; called by muse, mutect2, varscan2
- CHRNA6 | c.596_597insG p.D199Efs*7 | Frame Shift Ins (INS) | VAF 98/389 reads (25%) | catalogued as COSV52379529, COSV52379536; called by mutect2, pindel, varscan2
- CLCN3 | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 103/364 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs763040164; called by muse, mutect2, varscan2
- CLCN4 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 139/497 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66465285; called by muse, mutect2, varscan2
- CR1 | c.2701G>A p.D901N | Missense Mutation (SNP) | VAF 102/257 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.988); catalogued as rs571845275, COSV65455567, COSV65463610; called by muse, mutect2, varscan2
- DBX2 | c.976G>T p.E326* | Nonsense Mutation (SNP) | VAF 70/244 reads (29%) | catalogued as COSV60339138; called by muse, mutect2, varscan2
- DHRS7C | c.566G>A p.R189H (on ENST00000330255 / NM_001220493.2; = p.R188H on NM_001105571.3) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs757672468, COSV57649744, COSV57651074; called by muse, mutect2, varscan2
- DNAJC5B | c.534del p.T179Qfs*9 | Frame Shift Del (DEL) | VAF 33/135 reads (24%) | catalogued as COSV52537445; called by mutect2, pindel, varscan2
- DUS2 | c.1112A>T p.K371M | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62708530; called by muse, mutect2
- FAM47C | c.2398C>T p.R800C | Missense Mutation (SNP) | VAF 129/243 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as rs1263958797, COSV63726919; called by muse, mutect2, varscan2
- FBXO43 | c.1061C>A p.S354Y | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71053898; called by muse, mutect2, varscan2
- FBXW7 | c.1418+1G>A p.X473_splice (on ENST00000281708 / NM_001349798.2; = p.X393_splice on NM_018315.5) | Splice Site (SNP) | VAF 223/327 reads (68%) | catalogued as rs1371675972; called by muse, mutect2, varscan2
- FHOD3 | c.2314G>A p.V772I (on ENST00000359247 / NM_001281739.3; = p.V789I on NM_025135.5) | Missense Mutation (SNP) | VAF 84/150 reads (56%) | SIFT tolerated (0.39); PolyPhen benign (0.034); catalogued as rs754948359; called by muse, mutect2, varscan2
- FOXN2 | c.811A>C p.K271Q | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.987); catalogued as rs1347659394; called by muse, mutect2, varscan2
- GABRG1 | c.1130C>A p.S377* | Nonsense Mutation (SNP) | VAF 69/185 reads (37%) | catalogued as COSV54956064, COSV54963818; called by muse, mutect2, varscan2
- GPR158 | c.1684G>A p.G562R | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371219715; called by muse, mutect2, varscan2
- HAPLN3 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.895); catalogued as rs150514919; called by muse, mutect2, varscan2
- HECTD1 | c.6481-2A>G p.X2161_splice | Splice Site (SNP) | VAF 46/83 reads (55%) | catalogued as COSV67946307; called by muse, mutect2, varscan2
- HEG1 | c.1142C>T p.S381L | Missense Mutation (SNP) | VAF 111/268 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs373641692; called by muse, mutect2, varscan2
- IFT122 | c.2414G>A p.R805H (on ENST00000348417 / NM_052989.3; = p.R746H on NM_018262.4) | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs372519478, COSV56209635; called by muse, mutect2, varscan2
- IL13RA2 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 338/603 reads (56%) | SIFT tolerated (0.54); PolyPhen benign (0.017); catalogued as rs1219445525; called by muse, mutect2, varscan2
- KCNU1 | c.1342C>A p.Q448K | Missense Mutation (SNP) | VAF 106/281 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); catalogued as COSV67755821; called by muse, mutect2, varscan2
- KIF13B | c.2618A>T p.K873I | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.439); catalogued as COSV72954398; called by muse, mutect2, varscan2
- KIF2B | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV52135781, COSV99082061; called by muse, mutect2, varscan2
- MPP2 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs146765164; called by muse, mutect2, varscan2
- NPY4R | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs144429123, COSV65397802; called by muse, mutect2, varscan2
- NR0B1 | c.1292G>A p.S431N | Missense Mutation (SNP) | VAF 124/438 reads (28%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.767); catalogued as CD951561; called by muse, mutect2, varscan2
- OR5M1 | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 111/321 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV73202124; called by muse, mutect2, varscan2
- PABPC3 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 139/552 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV55800907; called by mutect2, varscan2
- PARP14 | c.4789C>T p.R1597C | Missense Mutation (SNP) | VAF 66/203 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs765698403, COSV71734687; called by muse, mutect2, varscan2
- PCDH17 | c.2335G>T p.A779S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as rs1392276258; called by muse, mutect2, varscan2
- PCDHA13 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as rs782439110, COSV56489639; called by muse, mutect2, varscan2
- PCDHGA3 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.166); catalogued as rs762497935; called by muse, mutect2, varscan2
- PIGM | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 15/560 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV63636068; called by muse, mutect2
- PIK3CA | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.904); catalogued as rs397517199, COSV104381248, COSV55880235, COSV55880477; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PML | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); catalogued as rs1475848935, COSV51446379; called by muse, mutect2, varscan2
- POMP | c.112G>C p.V38L | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as rs148838797; called by muse, mutect2, varscan2
- PRKCQ | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.144); catalogued as rs372791078; called by muse, mutect2, varscan2
- PYHIN1 | c.1002G>A p.T334= | Splice Region (SNP) | VAF 37/108 reads (34%) | catalogued as rs755380605; called by muse, mutect2, varscan2
- RALGPS1 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.191); catalogued as rs767763549, COSV52222756, COSV52236035; called by muse, mutect2, varscan2
- RGS22 | c.3472A>C p.K1158Q | Missense Mutation (SNP) | VAF 53/192 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.153); catalogued as COSV62661606; called by muse, mutect2, varscan2
- SACS | c.12481C>T p.P4161S | Missense Mutation (SNP) | VAF 64/246 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV66535325, COSV66543169; called by muse, mutect2, varscan2
- SCN5A | c.3859G>T p.V1287L (on ENST00000333535 / NM_198056.3; = p.V1286L on NM_000335.5) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.517); catalogued as COSV61124026; called by muse, mutect2, varscan2
- SFTPB | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV60893294; called by muse, varscan2
- SLC6A15 | c.1660A>G p.M554V | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs758867504; called by muse, mutect2, varscan2
- SLC6A17 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs781385140; called by muse, mutect2, varscan2
- SMARCC2 | c.595A>T p.K199* | Nonsense Mutation (SNP) | VAF 24/79 reads (30%) | catalogued as COSV57218144; called by muse, mutect2, varscan2
- TBC1D12 | c.1112C>T p.T371M | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs377630453; called by muse, mutect2, varscan2
- TEX13A | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 158/591 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.153); catalogued as rs781908901; called by muse, mutect2, varscan2
- TGIF1 | c.208C>G p.R70G (on ENST00000330513 / NM_001374396.1; = p.R90G on NM_003244.4) | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM020381, COSV57907509; called by muse, mutect2, varscan2
- TMEM167A | c.148+1G>T p.X50_splice | Splice Site (SNP) | VAF 31/88 reads (35%) | catalogued as rs1428222962; called by muse, mutect2, varscan2
- TNR | c.2578A>T p.I860F | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.632); catalogued as COSV99690459; called by muse, mutect2, varscan2
- TTN | c.100190C>T p.T33397I (on ENST00000591111; = p.T25973I on NM_003319.4) | Missense Mutation (SNP) | VAF 71/218 reads (33%) | PolyPhen possibly damaging (0.587); catalogued as COSV60059374; called by muse, mutect2, varscan2
- TTN | c.21682C>T p.R7228* (on ENST00000591111; = p.R6301* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 140/394 reads (36%) | catalogued as rs764687326, COSV59981876; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC13B | c.4219C>T p.R1407C | Missense Mutation (SNP) | VAF 113/359 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs150259776; called by muse, mutect2, varscan2
- USP25 | c.1427C>T p.S476F | Missense Mutation (SNP) | VAF 102/335 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV53483484; called by muse, mutect2, varscan2
- VTCN1 | c.573C>A p.F191L | Missense Mutation (SNP) | VAF 119/325 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV60222650; called by muse, mutect2, varscan2
- VWF | c.4705C>T p.R1569C | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as rs61909722; called by muse, mutect2, varscan2
- WNK3 | c.3262C>A p.Q1088K | Missense Mutation (SNP) | VAF 61/261 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV100671941; called by muse, mutect2, varscan2
- ZFHX4 | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 77/232 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.017); catalogued as rs1218726795, COSV50479906; called by muse, mutect2, varscan2
- ZFPL1 | c.695A>G p.D232G | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.305); catalogued as COSV51869518; called by muse, mutect2, varscan2
- ZGRF1 | c.1521A>C p.K507N | Missense Mutation (SNP) | VAF 118/318 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1016075482; called by muse, mutect2, varscan2
- ZNF229 | c.1142A>C p.E381A | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.074); catalogued as COSV52161861; called by muse, mutect2
- ZNF540 | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as rs200091894; called by muse, mutect2, varscan2
- ABCA10 | c.447C>A p.Y149* | Nonsense Mutation (SNP) | VAF 78/235 reads (33%) | called by muse, mutect2, varscan2
- ABITRAM | c.222_223dup p.S75Ifs*19 | Frame Shift Ins (INS) | VAF 80/259 reads (31%) | called by mutect2, pindel, varscan2
- ANKAR | c.2791G>T p.V931L | Missense Mutation (SNP) | VAF 7/215 reads (3%) | SIFT tolerated (0.63); PolyPhen benign (0.012); called by muse, mutect2
- ATXN7L3 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- BRCA2 | c.7046T>G p.F2349C | Missense Mutation (SNP) | VAF 120/493 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CBX3 | c.153G>C p.W51C | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CENPE | c.6941C>T p.S2314L | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- CLPB | c.2041G>C p.E681Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- DCAF12L2 | c.509A>C p.N170T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- DCAF17 | c.1453_1477del p.D485Nfs*13 | Frame Shift Del (DEL) | VAF 59/250 reads (24%) | called by mutect2, pindel, varscan2
- DOCK9 | c.137C>A p.S46* | Nonsense Mutation (SNP) | VAF 7/188 reads (4%) | called by muse, mutect2
- DPAGT1 | c.548C>G p.A183G | Missense Mutation (SNP) | VAF 87/236 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- DZIP3 | c.1887G>C p.Q629H | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.188); called by muse, mutect2
- FBXL7 | c.546del p.N183Tfs*9 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
- GTDC1 | c.58C>T p.L20F | Missense Mutation (SNP) | VAF 7/191 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IFT172 | c.2235G>T p.Q745H | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LRRN3 | c.1001C>G p.P334R | Missense Mutation (SNP) | VAF 72/274 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MBNL3 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- MESD | c.510C>G p.I170M | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- MYCBP2 | c.5293_5298dup p.Y1765_T1766dup (on ENST00000357337; = p.Y1803_T1804dup on NM_015057.5) | In Frame Ins (INS) | VAF 117/206 reads (57%) | called by mutect2, pindel, varscan2
- NAT2 | c.445dup p.I149Nfs*29 | Frame Shift Ins (INS) | VAF 36/187 reads (19%) | called by mutect2, pindel, varscan2
- NCAM2 | c.1304G>T p.R435I | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- OR5K4 | c.893T>G p.L298R | Missense Mutation (SNP) | VAF 280/936 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by mutect2, varscan2
- PCDHB14 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PKNOX2 | c.7C>T p.Q3* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- RAB40A | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 59/345 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); called by muse, varscan2
- SATB1 | c.970G>C p.A324P | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC16A2 | c.1420G>A p.G474R | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2
- SPTBN5 | c.6988G>A p.E2330K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- STAT4 | c.671A>C p.D224A | Missense Mutation (SNP) | VAF 128/338 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- TET1 | c.4693G>T p.G1565* | Nonsense Mutation (SNP) | VAF 119/317 reads (38%) | called by muse, mutect2, varscan2
- TREML1 | c.553G>T p.A185S | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- TTN | c.14206T>G p.S4736A (on ENST00000591111; = p.S3809A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/222 reads (36%) | PolyPhen benign (0.225); called by muse, mutect2, varscan2
- TTYH1 | c.912C>A p.N304K | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- ANKRD26 | c.5034C>T p.S1678= | Silent (SNP) | VAF 153/415 reads (37%) | catalogued as COSV65775483; called by muse, mutect2, varscan2
- CHRM2 | c.72G>T p.V24= | Silent (SNP) | VAF 116/170 reads (68%) | catalogued as COSV57772292; called by muse, mutect2, varscan2
- CMYA5 | c.10656T>C p.F3552= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV71405873; called by muse, mutect2, varscan2
- COL7A1 | c.7458C>T p.P2486= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs766547317, COSV60390948; called by muse, mutect2, varscan2
- CYP27C1 | c.312C>A p.I104= | Silent (SNP) | VAF 22/55 reads (40%) | called by muse, mutect2, varscan2
- CYP2J2 | c.435A>G p.L145= | Silent (SNP) | VAF 131/362 reads (36%) | catalogued as rs111798172; called by muse, mutect2, varscan2
- GPX6 | c.147C>T p.N49= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as rs767523979, COSV62657330, COSV62659016; called by muse, mutect2, varscan2
- H4C9 | c.141T>C p.I47= | Silent (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- HDAC9 | c.636T>C p.D212= | Silent (SNP) | VAF 95/294 reads (32%) | catalogued as COSV67773177; called by muse, mutect2, varscan2
- HSD3B2 | c.423C>T p.H141= | Silent (SNP) | VAF 87/255 reads (34%) | catalogued as rs751470493, COSV65593144; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- KIF2A | c.252C>T p.S84= | Silent (SNP) | VAF 55/177 reads (31%) | catalogued as COSV66945520; called by muse, mutect2, varscan2
- LHFPL5 | c.111C>T p.S37= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as rs757495483, COSV64177237; called by muse, mutect2, varscan2
- MAMLD1 | c.1737G>A p.T579= | Silent (SNP) | VAF 45/147 reads (31%) | catalogued as rs781895653, COSV53374842, COSV53379232; called by muse, mutect2, varscan2
- MFN1 | c.1333T>C p.L445= | Silent (SNP) | VAF 35/146 reads (24%) | catalogued as COSV54939631; called by muse, mutect2, varscan2
- MSL2 | c.30C>T p.Y10= | Silent (SNP) | VAF 121/346 reads (35%) | catalogued as rs771615352, COSV59442622; called by muse, mutect2, varscan2
- NR0B1 | c.606C>T p.C202= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs373712795, COSV66763572; called by muse, mutect2, varscan2
- OR4K5 | c.351G>T p.S117= | Silent (SNP) | VAF 288/509 reads (57%) | catalogued as COSV60002373, COSV60003499; called by muse, mutect2, varscan2
- PCDHA12 | c.546A>C p.I182= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV56484239; called by muse, mutect2, varscan2
- PGAP1 | c.1749T>C p.F583= | Silent (SNP) | VAF 32/125 reads (26%) | catalogued as COSV61326175; called by muse, mutect2, varscan2
- RAB40A | c.126G>A p.P42= | Silent (SNP) | VAF 234/414 reads (57%) | catalogued as rs748229696, COSV58491236; called by muse, varscan2
- RNF123 | c.1899C>A p.L633= | Silent (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- RPS6KA3 | c.255T>A p.V85= | Silent (SNP) | VAF 16/525 reads (3%) | called by muse, mutect2
- RSRP1 | c.597T>G p.A199= | Silent (SNP) | VAF 54/158 reads (34%) | called by muse, mutect2, varscan2
- RTEL1 | c.675G>A p.P225= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as rs762854518, COSV100541397, COSV58893505; called by muse, mutect2, varscan2
- SDSL | c.816G>T p.V272= | Silent (SNP) | VAF 26/406 reads (6%) | called by muse, mutect2
- SPDYE1 | c.363G>A p.V121= | Silent (SNP) | VAF 70/247 reads (28%) | catalogued as rs1479621675, COSV51670444; called by muse, mutect2, varscan2
- TMC2 | c.1341C>A p.L447= | Silent (SNP) | VAF 82/316 reads (26%) | called by muse, mutect2, varscan2
- TMEM130 | c.1266G>T p.L422= (on ENST00000416379 / NM_001134450.2; = p.L410= on NM_152913.3) | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs782685533; called by muse, mutect2, varscan2
- ZDBF2 | c.1173G>A p.E391= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as COSV65625947; called by muse, mutect2, varscan2
- DCHS2 | n.5411T>A | RNA (SNP) | VAF 88/277 reads (32%) | catalogued as COSV61771997; called by muse, mutect2, varscan2
